Somatic mutation profile of tumor specimen TCGA-EJ-5531-01A (aliquot TCGA-EJ-5531-01A-01D-1576-08) from TCGA case TCGA-EJ-5531, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,760 days).
Specimen TCGA-EJ-5531-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0dce97e-1877-48a2-99c1-580f5a492bb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5531-10A (Blood Derived Normal), aliquot TCGA-EJ-5531-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca79db6e-a515-4c5a-8fbb-997a5fe601b2

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.391T>C p.W131R | Missense Mutation (SNP) | VAF 30/265 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV61652911, COSV61653817; called by muse, mutect2, varscan2
- ACSM2B | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs750164112, COSV61657300; called by muse, mutect2
- ADGRB1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60094577; called by muse, mutect2
- ARHGAP32 | c.1048A>G p.M350V (on ENST00000310343 / NM_001378025.1; = p.M1? on NM_014715.4) | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV59846759; called by muse, mutect2, varscan2
- BLMH | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); catalogued as COSV55585309; called by muse, mutect2, varscan2
- CCL7 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV52336921; called by muse, mutect2
- CLN5 | c.432T>G p.C144W | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66284054; called by muse, mutect2
- EEF1E1 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs777312475, COSV65675517; called by muse, mutect2, varscan2
- ETV3L | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs202076672; called by muse, mutect2, varscan2
- GRIN2A | c.3367G>T p.E1123* | Nonsense Mutation (SNP) | VAF 22/363 reads (6%) | catalogued as rs775679737, COSV58030522; called by muse, mutect2
- IL7 | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.312); catalogued as COSV55674380, COSV55675133; called by muse, mutect2, varscan2
- INTS13 | c.348T>G p.D116E | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as COSV53902419; called by muse, mutect2
- KIR3DL1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 75/464 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV58490151; called by muse, mutect2, varscan2
- KMT2D | c.10180C>T p.Q3394* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV56434687; called by muse, mutect2, varscan2
- NTM | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs951593215, COSV66177489; called by muse, mutect2, varscan2
- OR4S2 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 23/350 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV56746626; called by muse, mutect2
- SARDH | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs558572942, COSV53833119; called by muse, mutect2, varscan2
- SLC1A2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 23/530 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53520910; called by muse, mutect2
- SLC22A10 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV60420873, COSV60421142; called by muse, mutect2, varscan2
- SSH1 | c.3069G>C p.R1023S | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV58456148; called by muse, mutect2, varscan2
- ZNF827 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | catalogued as COSV65226644; called by muse, mutect2, varscan2
- ANK3 | c.8251dup p.I2751Nfs*14 | Frame Shift Ins (INS) | VAF 17/151 reads (11%) | called by mutect2, varscan2
- FAM171A1 | c.1427del p.G476Afs*65 | Frame Shift Del (DEL) | VAF 21/138 reads (15%) | called by mutect2, varscan2
- FBXO6 | c.796del p.A266Pfs*95 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | called by mutect2, pindel
- CSAD | c.63C>T p.L21= (on ENST00000444623 / NM_001244705.2; = p.L48= on NM_015989.5) | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as COSV57242408; called by muse, mutect2
- HCRTR2 | c.780T>C p.S260= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV63795445; called by muse, mutect2, varscan2
- INTS7 | c.2574G>A p.L858= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as COSV65344226; called by muse, mutect2, varscan2
- MUC2 | c.1665C>T p.N555= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs766518239; called by muse, mutect2, varscan2
- ZNF519 | c.1545T>G p.P515= | Silent (SNP) | VAF 12/167 reads (7%) | catalogued as COSV73913322; called by muse, mutect2
- TEC | c.*1G>A | 3'UTR (SNP) | VAF 11/58 reads (19%) | catalogued as rs1385886645, COSV99972310; called by muse, mutect2, varscan2
